Somatic mutation profile of tumor specimen TCGA-QT-A5XL-01A (aliquot TCGA-QT-A5XL-01A-11D-A35D-08) from TCGA case TCGA-QT-A5XL, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 27.5 years (10,028 days).
Specimen TCGA-QT-A5XL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e120ccbd-c70b-4445-84c4-3471006a63c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QT-A5XL-10A (Blood Derived Normal), aliquot TCGA-QT-A5XL-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ded66a19-267b-476b-a7f1-0b688e9f6aae

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPAS1 | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 113/201 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55384498, COSV55386554, COSV55388056; called by muse, mutect2, varscan2
- RPRD2 | c.219C>A p.H73Q | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.154); catalogued as rs1553888809; called by muse, mutect2, varscan2
- RUNX1T1 | c.953C>T p.P318L (on ENST00000265814 / NM_001198628.1; = p.P291L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBEAL2 | c.4731G>A p.A1577= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs142878502; called by muse, mutect2, varscan2
- SERTM1 | c.27A>T p.G9= | Silent (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
